Gene-level copy-number profile of tumor specimen ALCH-B27P-TTP1-A from ALCHEMIST case ALCH-B27P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.5 years (27,211 days).
Specimen ALCH-B27P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1558eda2-7ea0-4e89-9d8a-05e5aad6f726.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B27P-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d9d5546e-1264-4056-a6ad-f65e2b5884d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 5,117; copy number 2: 53,077; copy number 3: 152; copy number 4: 19; copy number 5: 1; copy number 7: 3; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:66,505,155–66,592,397, 3 genes (within-gene range 0–1): AC008267.1, AC008267.3, AC006001.3.
- chr9:128,702,503–128,772,414, 6 genes: PKN3, RN7SL560P, ZDHHC12, AL441992.1, ZER1, Metazoa_SRP.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr12:131,896,500–131,898,239, 1 gene (within-gene range 0–2): AC131009.4.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 8: MIR5692C1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 8: BNIP3P6.
- chr19:1,259,384–1,279,244, 3 genes, copy number 7: CIRBP, CIRBP-AS1, FAM174C.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 2,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
